Somatic mutation profile of tumor specimen TCGA-HZ-A77P-01A (aliquot TCGA-HZ-A77P-01A-11D-A33T-08) from TCGA case TCGA-HZ-A77P, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 77.8 years (28,403 days).
Specimen TCGA-HZ-A77P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3238c2b6-3623-4f32-a84c-2599e08e2cb3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HZ-A77P-10A (Blood Derived Normal), aliquot TCGA-HZ-A77P-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b464f2f4-f5e9-4f47-ba46-2098279c27fc

The open-access MAF lists 45 somatic variants for this specimen: 35 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 9, Nonsense Mutation 2, Frame Shift Del 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP1A2 | c.1261C>T p.R421* | Nonsense Mutation (SNP) | VAF 11/129 reads (9%) | catalogued as rs1165052640, COSV63401955; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ADAMTS19 | c.3022G>A p.A1008T | Missense Mutation (SNP) | VAF 50/475 reads (11%) | SIFT tolerated (0.79); PolyPhen benign (0.026); catalogued as COSV99180547; called by muse, mutect2, varscan2
- AHRR | c.1662G>T p.W554C | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100327959; called by muse, mutect2
- BTN3A1 | c.235T>C p.Y79H | Missense Mutation (SNP) | VAF 83/957 reads (9%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV99176174; called by muse, mutect2
- CEP350 | c.2326G>T p.E776* | Nonsense Mutation (SNP) | VAF 61/574 reads (11%) | catalogued as COSV100855200; called by muse, mutect2, varscan2
- CEP350 | c.2884G>C p.D962H | Missense Mutation (SNP) | VAF 88/646 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.095); catalogued as COSV100855202; called by muse, mutect2, varscan2
- CHST11 | c.242G>T p.R81L | Missense Mutation (SNP) | VAF 32/409 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100359881, COSV57984419; called by muse, mutect2
- COL2A1 | c.4411G>A p.G1471R | Missense Mutation (SNP) | VAF 68/647 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56742634; called by muse, mutect2, varscan2
- CUL2 | c.1547C>T p.A516V | Missense Mutation (SNP) | VAF 26/241 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1347538705, COSV66078403, COSV66079131; called by muse, mutect2, varscan2
- DEFB119 | c.35T>C p.L12P | Missense Mutation (SNP) | VAF 131/735 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV100191189; called by muse, mutect2, varscan2
- DNAAF3 | c.712G>A p.V238I (on ENST00000524407 / NM_001256715.2; = p.V285I on NM_178837.4) | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.374); catalogued as rs1380206004, COSV100788022; ClinVar: uncertain significance; called by muse, mutect2
- EPB41L3 | c.1454G>A p.R485Q | Missense Mutation (SNP) | VAF 48/373 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.023); catalogued as rs767397189, COSV100550164; called by muse, mutect2, varscan2
- FOXD3 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 101/960 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100942928; called by muse, mutect2, varscan2
- FRY | c.4341A>T p.K1447N | Missense Mutation (SNP) | VAF 97/583 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.281); catalogued as COSV100969888; called by muse, mutect2, varscan2
- GPX5 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 53/482 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.396); catalogued as rs371361550; called by muse, mutect2, varscan2
- HSD17B12 | c.502-1G>T p.X168_splice | Splice Site (SNP) | VAF 45/538 reads (8%) | catalogued as rs921644038, COSV99551073; called by muse, mutect2
- HSPA1B | c.176T>C p.V59A | Missense Mutation (SNP) | VAF 31/568 reads (5%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.038); catalogued as COSV100989297; called by muse, mutect2
- LRRC45 | c.497T>G p.L166R | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV100141955; called by muse, mutect2
- MYH15 | c.5352G>T p.K1784N | Missense Mutation (SNP) | VAF 94/906 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV99844256; called by muse, mutect2, varscan2
- NFKBIZ | c.1621C>A p.Q541K | Missense Mutation (SNP) | VAF 63/573 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.878); catalogued as rs1321672011, COSV100397221, COSV100397255; called by muse, mutect2, varscan2
- OR4A47 | c.567C>A p.D189E | Missense Mutation (SNP) | VAF 78/872 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.094); catalogued as COSV101487107; called by muse, mutect2
- PCDHGB1 | c.124G>A p.G42S | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV54012625, COSV99530321, COSV99546418; called by muse, mutect2
- PDE3A | c.2585G>A p.R862H | Missense Mutation (SNP) | VAF 66/646 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62971149; called by muse, mutect2, varscan2
- SCN5A | c.2977G>A p.A993T | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs770088052, COSV100348699, COSV61129996; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEZ6L | c.2237C>T p.S746L | Missense Mutation (SNP) | VAF 45/406 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as rs574275567, COSV50660668, COSV99962339; called by muse, mutect2, varscan2
- SNX2 | c.1465G>A p.V489I | Missense Mutation (SNP) | VAF 26/296 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs760493667, COSV65347774; called by muse, mutect2
- SON | c.550G>T p.A184S | Missense Mutation (SNP) | VAF 59/517 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.23); catalogued as COSV99279718; called by muse, mutect2, varscan2
- SPSB4 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 26/303 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as rs79933965; called by muse, mutect2
- SVIL | c.1088C>T p.P363L | Missense Mutation (SNP) | VAF 40/408 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); catalogued as COSV100881528; called by muse, mutect2, varscan2
- TCF4 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 40/276 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV61890957; called by muse, mutect2, varscan2
- UBB | c.217C>G p.L73V | Missense Mutation (SNP) | VAF 52/475 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV100141714; called by muse, mutect2, varscan2
- UGP2 | c.1337T>C p.F446S | Missense Mutation (SNP) | VAF 28/350 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99708703; called by muse, mutect2
- XPO7 | c.1814G>A p.R605H | Missense Mutation (SNP) | VAF 20/191 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs762753271, COSV99382009; called by muse, mutect2, varscan2
- ZNF648 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 55/498 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs769628253, COSV100374767; called by muse, mutect2, varscan2
- CEP350 | c.2679_2685del p.Q894Cfs*18 | Frame Shift Del (DEL) | VAF 48/510 reads (9%) | called by mutect2, pindel
- ANKRD24 | c.3042C>T p.H1014= | Silent (SNP) | VAF 66/606 reads (11%) | catalogued as rs764148400, COSV53673686; called by muse, mutect2, varscan2
- ARNTL | c.1875G>T p.P625= (on ENST00000403290 / NM_001297719.2; = p.P624= on NM_001178.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 43/556 reads (8%) | catalogued as rs760799974, COSV99533903; called by muse, mutect2
- ESR2 | c.783C>T p.D261= | Silent (SNP) | VAF 79/357 reads (22%) | catalogued as rs750886730, COSV50828395; called by muse, mutect2, varscan2
- FGF23 | c.366C>T p.N122= | Silent (SNP) | VAF 92/819 reads (11%) | catalogued as rs145147639; called by muse, mutect2, varscan2
- KCNIP2 | c.156C>T p.P52= | Silent (SNP) | VAF 22/165 reads (13%) | catalogued as COSV99493609; called by muse, mutect2
- MATN2 | c.2667C>T p.D889= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV99647102; called by muse, mutect2
- PAX6 | c.342C>T p.N114= | Silent (SNP) | VAF 50/465 reads (11%) | catalogued as COSV53796085; called by muse, mutect2, varscan2
- SIPA1 | c.573C>T p.N191= | Silent (SNP) | VAF 35/452 reads (8%) | catalogued as rs764727662, COSV63136633; called by muse, mutect2
- TAF2 | c.2712T>C p.Y904= | Silent (SNP) | VAF 68/784 reads (9%) | catalogued as COSV100978796; called by muse, mutect2
- BTN2A3P | n.1039G>C | RNA (SNP) | VAF 62/696 reads (9%) | called by muse, mutect2
